Somatic mutation profile of tumor specimen TCGA-AJ-A5DW-01A (aliquot TCGA-AJ-A5DW-01A-11D-A27P-09) from TCGA case TCGA-AJ-A5DW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 56.7 years (20,711 days).
Specimen TCGA-AJ-A5DW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e73a03a-4969-4a6a-998d-a66a1f05ad4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A5DW-10A (Blood Derived Normal), aliquot TCGA-AJ-A5DW-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82448c5a-0ca8-47e3-9e10-1ab45bf16df4

The open-access MAF lists 3,613 somatic variants for this specimen: 2,903 protein-altering or splice-affecting, 616 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,360, Silent 616, Nonsense Mutation 464, Splice Site 47, RNA 37, Intron 36, Splice Region 19, Frame Shift Ins 9, 3'UTR 6, 3'Flank 6, 5'Flank 5, 5'UTR 4.

Variants (750 of 3,613; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2869C>T p.R957* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs121918440, CM981521, COSV55934187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs199422227, CM920368, COSV61712686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.11410C>T p.R3804* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs767570081, COSV67994591; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as rs1555904878, COSV61306169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4634C>A p.S1545* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs863225356, CM023012, COSV57326602, COSV57339509, COSV57340522; ClinVar: pathogenic; called by muse, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6AP1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs878853277, CM166855, COSV63895463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs121918314, COSV65353611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs1085307204, CM094639, CM100457, COSV101001509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as rs80356875, CM990288, COSV58797263; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHAT | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912822, CM014854, COSV100339471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80356686, CM023902, CM032879, COSV58370212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs104886169, CM085959, COSV100087866; ClinVar: pathogenic; called by muse, varscan2
- COL6A3 | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs912671116, COSV55090355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EDA | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs387907197, CM098466, COSV101000009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPG5 | c.7333C>T p.R2445* | Nonsense Mutation (SNP) | VAF 12/16 reads (75%) | catalogued as rs780889226, CM163403, COSV99957314, COSV99957326; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FBXL4 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs754142863, CM159511, CM159512, COSV100014015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- GFM2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs761283105, COSV57191541; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MED23 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766478634, COSV51580995; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NR3C2 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121912573, CM065346, CM124521, COSV61000655; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTX2 | c.265C>T p.R89* (on ENST00000408990 / NM_172337.3; = p.R97* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs104894464, CM051593, CM104945, COSV59766659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- P2RY12 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121917885, CM035078, COSV56386348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PEX2 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs61752124, CM981684, COSV63813349; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SCN5A | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs199473045, CM024633, COSV60067291; ClinVar: pathogenic / likely benign / not provided; called by muse, mutect2, varscan2
- SYNGAP1 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs1057518352, COSV53385610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10612C>T p.R3538* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs878853413, CM159124, COSV56359453; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377622666; called by muse, mutect2, varscan2
- A2ML1 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV100228952; called by muse, mutect2, varscan2
- AASDH | c.2973A>C p.K991N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52709799, COSV99221314; called by muse, mutect2, varscan2
- ABCA1 | c.6772G>T p.E2258* | Nonsense Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as COSV101037015; called by muse, mutect2, varscan2
- ABCA10 | c.2837T>C p.V946A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV99288667; called by muse, mutect2, varscan2
- ABCA10 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs1276707545, COSV99288668; called by muse, mutect2, varscan2
- ABCA13 | c.13750C>A p.L4584I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV101291348; called by muse, mutect2, varscan2
- ABCA5 | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV67015797; called by muse, mutect2, varscan2
- ABCA6 | c.3911G>A p.R1304K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as COSV99446539; called by muse, mutect2, varscan2
- ABCA6 | c.3814G>T p.D1272Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1425612597, COSV99446541; called by muse, mutect2, varscan2
- ABCA6 | c.3247G>T p.E1083* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99446543; called by muse, mutect2, varscan2
- ABCA6 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs745713208, COSV52636883; called by mutect2, varscan2
- ABCA6 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs771243934, COSV52641606, COSV99447676; called by muse, mutect2
- ABCA8 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52201379; called by muse, mutect2, varscan2
- ABCA9 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100383131; called by mutect2, varscan2
- ABCB11 | c.2990C>A p.S997Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55596172; called by muse, mutect2, varscan2
- ABCB4 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99710501; called by muse, mutect2, varscan2
- ABCB5 | c.1537-1G>T p.X513_splice (on ENST00000404938 / NM_001163941.2; = p.X68_splice on NM_178559.6) | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99328457; called by muse, mutect2, varscan2
- ABCB5 | c.2044T>G p.L682V (on ENST00000404938 / NM_001163941.2; = p.L237V on NM_178559.6) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV99328459; called by muse, mutect2, varscan2
- ABCB7 | c.1832G>A p.G611E (on ENST00000373394 / NM_001271696.3; = p.G612E on NM_004299.6) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53723042, COSV99504394; called by muse, varscan2
- ABCC2 | c.3062A>G p.D1021G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100966543; called by muse, mutect2, varscan2
- ABCC2 | c.4094T>G p.I1365S | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100966544; called by muse, mutect2, varscan2
- ABCC6 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99228834; called by muse, mutect2, varscan2
- ABCC6 | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV99228836; called by muse, mutect2, varscan2
- ABCG1 | c.1956C>A p.F652L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV100494208; called by muse, mutect2, varscan2
- ABHD17C | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV99358681; called by muse, mutect2, varscan2
- ABHD5 | c.283T>G p.F95V | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99185480; called by muse, mutect2, varscan2
- ABHD6 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs754217725, COSV55908871; called by muse, mutect2, varscan2
- AC020907.6 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100032574; called by muse, mutect2, varscan2
- AC024940.1 | n.4599C>T | Splice Region (SNP) | VAF 72/190 reads (38%) | catalogued as rs933609555; called by muse, mutect2, varscan2
- AC090517.4 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403438618, COSV99974532; called by muse, mutect2, varscan2
- AC098582.1 | c.726A>C p.Q242H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1202365256, COSV99985627; called by muse, mutect2, varscan2
- AC098582.1 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018883, COSV52022658; called by muse, mutect2, varscan2
- ACACA | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1357271377; called by muse, mutect2, varscan2
- ACADM | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100897678; called by muse, mutect2, varscan2
- ACAN | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100718176; called by muse, mutect2, varscan2
- ACER3 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV99568344; called by muse, mutect2, varscan2
- ACOX1 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs147255787, COSV53138190; called by muse, mutect2, varscan2
- ACP2 | c.194T>G p.F65C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99922255; called by muse, mutect2, varscan2
- ACSBG2 | c.1060T>A p.F354I | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99397437; called by muse, mutect2, varscan2
- ACSL3 | c.1847+1G>A p.X616_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100657948; called by muse, mutect2, varscan2
- ACSM2B | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1457653822, COSV61657878; called by muse, mutect2, varscan2
- ACTB | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV100079661, COSV59321358; called by muse, mutect2, varscan2
- ACTR1B | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs535608880, COSV56703646; called by muse, mutect2, varscan2
- ADA2 | c.872C>T p.S291L (on ENST00000262607; = p.S50L on NM_177405.3) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1390146619, COSV52833893; called by muse, mutect2, varscan2
- ADAD1 | c.216T>G p.I72M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as COSV99635696; called by muse, mutect2, varscan2
- ADAD1 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99635698; called by muse, mutect2, varscan2
- ADAM10 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99546123; called by muse, mutect2, varscan2
- ADAM2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.374); catalogued as COSV99697365; called by muse, mutect2, varscan2
- ADAM21 | c.1856G>T p.C619F | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99961041; called by muse, mutect2, varscan2
- ADAM7 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99443010, COSV99444672; called by muse, mutect2, varscan2
- ADAMDEC1 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as COSV99836081; called by muse, mutect2
- ADAMTS1 | c.2640A>T p.E880D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV99536173; called by muse, mutect2, varscan2
- ADAMTS3 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV54401790; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs771490066, COSV99719012; called by muse, mutect2
- ADCY10 | c.360T>G p.I120M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100896883; called by muse, varscan2
- ADCY3 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs772293701, COSV53172390; called by muse, mutect2, varscan2
- ADCY9 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV53580542; called by muse, mutect2, varscan2
- ADGRA3 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs771076973, COSV51565862; called by muse, mutect2, varscan2
- ADGRB1 | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV100029736; called by muse, mutect2, varscan2
- ADGRB3 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000817; called by muse, mutect2, varscan2
- ADGRF5 | c.2852A>G p.E951G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1294849331, COSV99345658; called by muse, mutect2, varscan2
- ADGRG2 | c.1556del p.A519Vfs*13 (on ENST00000379869 / NM_001079858.3; = p.A516Vfs*13 on NM_005756.4) | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV61341242; called by mutect2, pindel, varscan2
- ADGRG2 | c.691G>T p.E231* (on ENST00000379869 / NM_001079858.3; = p.E228* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100492279, COSV61341481; called by muse, mutect2, varscan2
- ADGRG2 | c.320G>T p.R107I (on ENST00000379869 / NM_001079858.3; = p.R104I on NM_005756.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.122); catalogued as COSV100492280, COSV100492436; called by muse, mutect2, varscan2
- ADGRG4 | c.402A>C p.E134D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99795600; called by muse, mutect2
- ADGRG4 | c.6854C>A p.S2285Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99795602; called by muse, mutect2, varscan2
- ADGRG4 | c.7901C>A p.S2634* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99795603; called by muse, mutect2, varscan2
- ADGRV1 | c.5408C>A p.S1803Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.979); catalogued as rs371348667, COSV67990524; called by mutect2, varscan2
- ADGRV1 | c.10852G>T p.E3618* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101316022, COSV67986483; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2, varscan2
- ADGRV1 | c.16780C>T p.R5594C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs376062087; called by muse, mutect2, varscan2
- ADNP2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs752046762, COSV100080899; called by muse, mutect2, varscan2
- ADSS1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100272281; called by muse, mutect2, varscan2
- AFF3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs190577667, COSV57838935; called by muse, mutect2, varscan2
- AFG3L2 | c.293-1G>A p.X98_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99301913; called by muse, mutect2, varscan2
- AFTPH | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs764819647, COSV99480789; called by muse, mutect2, varscan2
- AGAP2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1395402183, COSV99223260; called by muse, mutect2, varscan2
- AGBL1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs201541206; called by muse, mutect2, varscan2
- AGBL2 | c.1582C>A p.L528M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV100101718; called by muse, mutect2, varscan2
- AGBL4 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100484287; called by muse, mutect2, varscan2
- AGER | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as COSV100904984; called by muse, mutect2, varscan2
- AGGF1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100461879; called by muse, mutect2
- AGK | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100814637; called by muse, mutect2, varscan2
- AGMO | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100693961; called by muse, mutect2, varscan2
- AGPAT3 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99377472; called by muse, mutect2, varscan2
- AGTR2 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100903574; called by muse, mutect2, varscan2
- AGXT2 | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV99183759; called by muse, mutect2, varscan2
- AHCTF1 | c.2519C>A p.S840Y (on ENST00000366508; = p.S814Y on NM_015446.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100403755; called by muse, mutect2, varscan2
- AHCTF1 | c.1321C>A p.R441S (on ENST00000366508; = p.R415S on NM_015446.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100403758, COSV58252915; called by muse, mutect2, varscan2
- AHCTF1 | c.925G>T p.E309* (on ENST00000366508; = p.E283* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100403761; called by muse, mutect2, varscan2
- AHNAK | c.2876A>C p.K959T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV99947652; called by muse, mutect2, varscan2
- AHNAK2 | c.13662C>A p.F4554L | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.093); catalogued as COSV100316446, COSV100317622; called by muse, mutect2, varscan2
- AIM2 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100931077, COSV63701478; called by muse, mutect2, varscan2
- AK5 | c.485C>A p.S162Y (on ENST00000354567 / NM_174858.3; = p.S136Y on NM_012093.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222950271, COSV100481494; called by muse, mutect2, varscan2
- AK7 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99967280; called by muse, mutect2
- AKAP11 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99213959; called by muse, mutect2, varscan2
- AKAP13 | c.6217C>A p.L2073I (on ENST00000394518 / NM_007200.5; = p.L2077I on NM_006738.6) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV100773844; called by muse, mutect2, varscan2
- AKAP5 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100277990; called by muse, mutect2, varscan2
- AKAP7 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV100818787; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKAP9 | c.11368C>T p.R3790W (on ENST00000359028; = p.R3766W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774732981, COSV100662142; called by muse, mutect2, varscan2
- AKNAD1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770288962, COSV100645556; called by muse, mutect2, varscan2
- AKR1C4 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99578720; called by muse, mutect2, varscan2
- AKR7A3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs756610725, COSV64389201; called by muse, mutect2, varscan2
- AKT3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55609365; called by muse, mutect2, varscan2
- AL592490.1 | c.2787G>T p.Q929H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV101308202; called by muse, mutect2, varscan2
- ALAD | c.884A>C p.D295A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99474786; called by muse, mutect2
- ALAD | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1249890466, COSV52959492; called by muse, mutect2, varscan2
- ALAS2 | c.971T>G p.I324S | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238362; called by muse, mutect2, varscan2
- ALB | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV55735427, COSV99891536; called by muse, mutect2, varscan2
- ALCAM | c.803T>G p.L268R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100064838; called by muse, mutect2, varscan2
- ALDH1L2 | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV51558053; called by muse, mutect2, varscan2
- ALDH5A1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs772361710, COSV100708811; called by muse, mutect2
- ALDH9A1 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV61339444; called by muse, mutect2, varscan2
- ALG1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52158127, COSV99275771; called by muse, mutect2, varscan2
- ALG13 | c.2091T>C p.R697= | Splice Region (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99322305; called by muse, mutect2, varscan2
- ALG14 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV100930861, COSV64635270; called by muse, mutect2, varscan2
- ALG5 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1345234730, COSV99523675; called by muse, mutect2, varscan2
- ALMS1 | c.6297G>T p.E2099D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV100042542; called by muse, mutect2, varscan2
- ALOX15 | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99541444; called by muse, mutect2, varscan2
- ALOX15B | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101205621; called by muse, varscan2
- ALPK2 | c.4982A>C p.E1661A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100864421; called by muse, mutect2, varscan2
- ALS2 | c.2940G>T p.E980D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99968539, COSV99969332; called by muse, mutect2, varscan2
- ALX4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.85); catalogued as rs774043649, COSV61326736; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2
- AMMECR1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99466195; called by mutect2, varscan2
- AMPD2 | c.1308T>G p.F436L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99857758; called by muse, mutect2, varscan2
- AMY1C | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs748093326, COSV100915209; called by muse, mutect2, varscan2
- ANGPTL3 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs375934830; called by muse, mutect2, varscan2
- ANK2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001787; called by muse, mutect2, varscan2
- ANK3 | c.5237C>A p.S1746Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs754173928, COSV55071553, COSV55072795; called by muse, mutect2, varscan2
- ANK3 | c.4160T>G p.F1387C (on ENST00000280772 / NM_001320874.2; = p.F521C on NM_001149.3) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99780130; called by muse, mutect2, varscan2
- ANKAR | c.2884C>A p.Q962K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99854284; called by muse, mutect2, varscan2
- ANKFY1 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs371815650; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, mutect2
- ANKRD20A2P | c.2394G>T p.Q798H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV101111835; called by muse, mutect2, varscan2
- ANKRD24 | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV53667361, COSV53668764; called by muse, mutect2
- ANKRD30A | c.4183G>T p.E1395* (on ENST00000611781; = p.E1339* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100653594, COSV100654643; called by muse, mutect2
- ANKRD54 | c.720+2T>C p.X240_splice | Splice Site (SNP) | VAF 26/50 reads (52%) | catalogued as COSV99316484; called by muse, mutect2, varscan2
- ANKS6 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs541130489, COSV100782294, COSV62049018; called by muse, mutect2, varscan2
- ANO2 | c.2337G>T p.K779N (on ENST00000356134 / NM_001278597.3; = p.K783N on NM_001278596.3) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100501105; called by muse, mutect2, varscan2
- ANO2 | c.2223G>T p.E741D (on ENST00000356134 / NM_001278597.3; = p.E745D on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100501106; called by muse, mutect2, varscan2
- ANO4 | c.337C>T p.R113* (on ENST00000392977 / NM_001286615.2; = p.R78* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as rs766790643, COSV54609036; called by muse, mutect2, varscan2
- ANO4 | c.2042G>A p.R681Q (on ENST00000392977 / NM_001286615.2; = p.R646Q on NM_178826.4) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs774283498, COSV54603606; called by muse, mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- ANO5 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs370084681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100201884; called by muse, varscan2
- ANO9 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100230056, COSV60384401; called by muse, mutect2, varscan2
- ANPEP | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as rs1025516664, COSV100263098, COSV55592270; called by muse, mutect2, varscan2
- AP000721.1 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 36/111 reads (32%) | PolyPhen probably damaging (0.937); catalogued as COSV100034331; called by muse, mutect2, varscan2
- AP002512.3 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs749473920, COSV54405969; called by muse, mutect2, varscan2
- AP002512.3 | c.775A>G p.S259G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.702); catalogued as COSV99687968; called by mutect2, varscan2
- AP4B1 | c.2069G>A p.G690D | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV99870645, COSV99871081; called by muse, mutect2, varscan2
- AP4B1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56724890; called by muse, mutect2, varscan2
- AP5Z1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs767325342, COSV100804143; called by muse, varscan2
- APC | c.7720C>A p.L2574I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs876659753, COSV57384137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99279472; called by muse, mutect2, varscan2
- APLF | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769480335, COSV100377003, COSV58143504; called by muse, mutect2
- APOB | c.13359C>A p.S4453R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV99265774; called by muse, mutect2, varscan2
- APOB | c.11029C>A p.L3677I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV99265777; called by muse, mutect2, varscan2
- APOB | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51949891; called by muse, mutect2, varscan2
- APOL3 | c.373G>A p.E125K (on ENST00000349314 / NM_145640.2; = p.E54K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.566); catalogued as rs573296139, COSV100652083; called by mutect2, varscan2
- APTX | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100541365, COSV58929604; called by muse, mutect2, varscan2
- ARAP2 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as rs868517624, COSV58282896; called by muse, mutect2, varscan2
- ARFGEF1 | c.3836T>G p.F1279C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99142468; called by muse, mutect2, varscan2
- ARHGAP10 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100331268; called by muse, mutect2, varscan2
- ARHGAP12 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100260614; called by muse, mutect2, varscan2
- ARHGAP17 | c.2618A>G p.D873G (on ENST00000289968 / NM_001006634.3; = p.D795G on NM_018054.6) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV99253475; called by muse, mutect2, varscan2
- ARHGAP17 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99253479; called by muse, mutect2, varscan2
- ARHGAP26 | c.155-1G>T p.X52_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99190978; called by muse, mutect2, varscan2
- ARHGAP32 | c.4714G>A p.E1572K (on ENST00000310343 / NM_001378025.1; = p.E1223K on NM_014715.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200206728, COSV59843905; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP9 | c.1852G>T p.D618Y (on ENST00000393797 / NM_001319850.2; = p.D599Y on NM_032496.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57361841, COSV57366220, COSV99954177; called by muse, mutect2, varscan2
- ARHGEF12 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV100754939, COSV63102481; called by muse, mutect2, varscan2
- ARHGEF25 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs773245828, COSV99677993; called by mutect2, varscan2
- ARHGEF6 | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51698271; called by muse, mutect2, varscan2
- ARID2 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100536269; called by muse, mutect2, varscan2
- ARID2 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as COSV100537195, COSV57610197; called by muse, mutect2, varscan2
- ARID5B | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV54424825; called by muse, mutect2, varscan2
- ARL14 | c.117T>G p.I39M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100296480; called by mutect2, varscan2
- ARL4A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs749392270, COSV100775926; called by muse, mutect2, varscan2
- ARMC10 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100085744, COSV58521400; called by muse, mutect2, varscan2
- ARMC3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1021320309, COSV53067927; called by muse, mutect2, varscan2
- ARMC8 | c.856C>T p.R286* (on ENST00000469044 / NM_001363941.2; = p.R272* on NM_014154.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV61767906; called by muse, mutect2, varscan2
- ARMCX3 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100362272; called by muse, mutect2, varscan2
- ARMCX5 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as rs951073931, COSV99863404; called by muse, mutect2, varscan2
- ARMH4 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99958257, COSV99958835; called by muse, mutect2, varscan2
- ARMT1 | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.371); catalogued as COSV100939801; called by muse, mutect2, varscan2
- ARNTL | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62985752; called by muse, mutect2, varscan2
- ARVCF | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144187900, COSV52889222; called by muse, mutect2, varscan2
- ASAH1 | c.504dup p.G169Rfs*21 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs768342020; called by pindel, varscan2
- ASAP2 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as COSV99856247; called by muse, mutect2, varscan2
- ASB13 | c.381C>T p.S127= | Splice Region (SNP) | VAF 19/44 reads (43%) | catalogued as rs372624367, COSV63090821; called by muse, mutect2, varscan2
- ASB18 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV100430618; called by muse, mutect2, varscan2
- ASB5 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56668461, COSV56670474; called by muse, varscan2
- ASCC1 | c.1005G>T p.K335N (on ENST00000342444 / NM_001369085.1; = p.K307N on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100403380; called by muse, mutect2, varscan2
- ASCC1 | c.562A>G p.K188E (on ENST00000342444 / NM_001369085.1; = p.K160E on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.194); catalogued as COSV100403382; called by muse, mutect2, varscan2
- ASH1L | c.929C>A p.T310N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.07); catalogued as COSV100853432; called by muse, mutect2, varscan2
- ASRGL1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs200906420, COSV57126022; called by muse, mutect2, varscan2
- ASTN1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV99921820; called by muse, mutect2, varscan2
- ASXL3 | c.772C>A p.L258I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99325030; called by muse, mutect2, varscan2
- ASXL3 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV52462250; called by muse, mutect2, varscan2
- ASXL3 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.299); catalogued as COSV52461194; called by muse, mutect2, varscan2
- ATAD3A | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59236514; called by muse, mutect2, varscan2
- ATG10 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99966900, COSV99967357; called by muse, mutect2, varscan2
- ATG4C | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs760611137, COSV100508160, COSV58605534; called by muse, mutect2, varscan2
- ATG5 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100576378; called by muse, mutect2, varscan2
- ATM | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs141087784, CM014033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.251); catalogued as rs769443660, COSV100017797; called by muse, mutect2, varscan2
- ATP11C | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100557977; called by muse, mutect2, varscan2
- ATP11C | c.867-1G>T p.X289_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100557981; called by muse, mutect2, varscan2
- ATP12A | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs760144732, COSV99517703; called by muse, varscan2
- ATP12A | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54514387; called by muse, mutect2, varscan2
- ATP2A3 | c.3071G>T p.R1024I (on ENST00000352011 / NM_174955.3; = p.E995* on NM_005173.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99989163; called by muse, mutect2
- ATP2B1 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1565806870, COSV99665742; called by muse, mutect2, varscan2
- ATP2B3 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.509); catalogued as rs782400729, COSV99684561; called by muse, mutect2, varscan2
- ATP2C1 | c.2905G>T p.D969Y (on ENST00000507488 / NM_001378511.1; = p.D945Y on NM_001001486.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99393822; called by muse, mutect2, varscan2
- ATP6V0D2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs781030035, COSV53413746; called by muse, mutect2, varscan2
- ATP6V1B2 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99369438; called by muse, mutect2, varscan2
- ATP6V1H | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.815); catalogued as COSV100778647; called by muse, mutect2, varscan2
- ATP7A | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1557232786, COSV58451518; called by muse, mutect2, varscan2
- ATRX | c.3383G>T p.R1128I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100970819; called by muse, mutect2, varscan2
- AXDND1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV62642368; called by muse, mutect2, varscan2
- AZIN1 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61479308; called by muse, mutect2, varscan2
- B3GALT2 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100813604; called by muse, mutect2, varscan2
- B3GNT5 | c.93T>G p.F31L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100192661; called by muse, mutect2, varscan2
- B3GNT5 | c.1095T>G p.I365M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as COSV100192663; called by muse, mutect2, varscan2
- B9D2 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.217); catalogued as COSV99699148; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BAD | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99657439; called by muse, mutect2, varscan2
- BAG6 | c.3275G>A p.R1092H (on ENST00000676571; = p.R1045H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99277058; called by mutect2, varscan2
- BANK1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.461); catalogued as rs998626392, COSV100536370, COSV100536570; called by muse, mutect2, varscan2
- BAZ2B | c.4372C>A p.L1458I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100600660; called by muse, mutect2, varscan2
- BBS2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as COSV99802445; called by muse, mutect2, varscan2
- BBS5 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV54751827, COSV99751953; called by muse, mutect2, varscan2
- BBS7 | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99144949; called by muse, mutect2, varscan2
- BBS7 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99144950; called by muse, mutect2, varscan2
- BBS9 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54165035; called by muse, mutect2, varscan2
- BCAR3 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV53074603; called by muse, mutect2, varscan2
- BCAS3 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV66783107; called by muse, mutect2
- BCCIP | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.09); catalogued as rs1401782684, COSV52939292; called by muse, mutect2, varscan2
- BCL10 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65353663, COSV65353778; called by muse, mutect2, varscan2
- BCLAF1 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99219577; called by muse, mutect2, varscan2
- BCLAF3 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100503304; called by muse, mutect2, varscan2
- BCOR | c.5000C>T p.S1667L (on ENST00000378444 / NM_001123385.2; = p.S1633L on NM_017745.6) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754470140, COSV100653358; called by muse, mutect2
- BCORL1 | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99499656; called by muse, mutect2, varscan2
- BCR | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.399); catalogued as COSV100006561, COSV59930861; called by muse, mutect2, varscan2
- BDP1 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100703107, COSV62432329; called by muse, mutect2, varscan2
- BEND2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759938608, COSV66214944; called by muse, mutect2, varscan2
- BEND4 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV101549752, COSV101549764; called by muse, mutect2, varscan2
- BEST4 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV100944016, COSV64734464; called by muse, mutect2, varscan2
- BET1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV99747271; called by muse, mutect2, varscan2
- BFSP1 | c.1956G>T p.K652N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100925371; called by muse, mutect2, varscan2
- BFSP1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100925372; called by muse, mutect2, varscan2
- BFSP2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as rs767599025, COSV56593012; called by muse, mutect2, varscan2
- BICDL1 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV101287343; called by muse, mutect2, varscan2
- BICDL1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99985835; called by muse, mutect2, varscan2
- BIRC6 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs751973111, COSV101428327; called by muse, mutect2, varscan2
- BIRC6 | c.9143C>A p.S3048Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101428328, COSV70200389, COSV70202778; called by mutect2, varscan2
- BIRC6 | c.12151G>T p.E4051* | Nonsense Mutation (SNP) | VAF 40/72 reads (56%) | catalogued as COSV101134341; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99958780; called by muse, mutect2
- BMF | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.323); catalogued as COSV99590441; called by muse, mutect2
- BMP2 | c.347-1G>T p.X116_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV66579474; called by muse, varscan2
- BMP2 | c.405T>G p.N135K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV101122088; called by muse, varscan2
- BMP2K | c.552A>C p.E184D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100621758; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61757496; called by muse, mutect2, varscan2
- BNIP2 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99985760; called by muse, mutect2
- BNIP5 | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101465152; called by muse, mutect2, varscan2
- BPIFC | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV100300813; called by muse, mutect2, varscan2
- BRCA2 | c.3330A>C p.E1110D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs369294255, COSV101204261; ClinVar: uncertain significance; called by mutect2, varscan2
- BRD8 | c.209A>C p.E70A | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99137030; called by muse, mutect2, varscan2
- BRDT | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs368068707; called by muse, varscan2
- BRMS1L | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53762926; called by muse, mutect2, varscan2
- BRS3 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101036581, COSV65710663; called by muse, mutect2, varscan2
- BRS3 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65710838, COSV65710893; called by muse, mutect2, varscan2
- BRWD1 | c.1260A>C p.E420D | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV100313467; called by muse, mutect2, varscan2
- BRWD1 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313468; called by muse, mutect2, varscan2
- BSN | c.4879_4880insA p.L1627Hfs*12 | Frame Shift Ins (INS) | VAF 16/39 reads (41%) | catalogued as COSV99608573; called by mutect2, pindel, varscan2
- BTAF1 | c.4555G>T p.D1519Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56439626, COSV99795382; called by muse, mutect2
- BTBD11 | c.3139G>A p.E1047K (on ENST00000280758 / NM_001018072.2; = p.E584K on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs34000924; called by muse, mutect2, varscan2
- BTBD9 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757637334, COSV58431339; called by muse, mutect2, varscan2
- BTG2 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV99305775; called by muse, mutect2, varscan2
- BTN3A1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV99175828; called by muse, mutect2, varscan2
- BZW2 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV99334602; called by muse, mutect2, varscan2
- C12orf4 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV99712749; called by muse, mutect2, varscan2
- C12orf50 | c.684A>C p.K228N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100072260; called by muse, mutect2, varscan2
- C12orf56 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100399445; called by muse, mutect2, varscan2
- C12orf60 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99966910; called by muse, mutect2, varscan2
- C14orf93 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as rs374314595; called by muse, mutect2, varscan2
- C16orf87 | c.220A>C p.N74H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99587540; called by muse, mutect2, varscan2
- C17orf80 | c.1523T>A p.L508* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99278115; called by muse, mutect2, varscan2
- C19orf54 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99648768; called by muse, mutect2, varscan2
- C1GALT1C1 | c.332T>G p.I111S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV100485616; called by muse, mutect2, varscan2
- C1orf141 | c.730A>C p.N244H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV100924343; called by muse, mutect2, varscan2
- C1orf141 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV100924344; called by muse, mutect2, varscan2
- C1orf50 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100998110; called by muse, mutect2, varscan2
- C1orf52 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401446398, COSV99641004; called by muse, mutect2, varscan2
- C20orf194 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52702614; called by muse, mutect2, varscan2
- C22orf31 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs371011517; called by muse, mutect2, varscan2
- C2CD3 | c.5481C>A p.F1827L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100486762; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C3 | c.2275G>T p.E759* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99836690; called by muse, mutect2, varscan2
- C3 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55578565, COSV99836730; called by muse, mutect2, varscan2
- C3orf33 | c.447G>T p.E149D (on ENST00000340171 / NM_001308229.2; = p.E106D on NM_173657.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV100420083, COSV100420129; called by muse, mutect2, varscan2
- C5 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99797933; called by muse, mutect2, varscan2
- C6 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99667135; called by muse, mutect2, varscan2
- C6 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54711749; called by muse, varscan2
- C7 | c.590A>C p.N197T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV100495858; called by muse, varscan2
- C9 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99662080; called by muse, mutect2, varscan2
- CA14 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs146764019; called by muse, mutect2, varscan2
- CA2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs773013094, COSV53406436, COSV53408039; called by muse, mutect2, varscan2
- CABP2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs777036556, COSV99590819; called by muse, mutect2, varscan2
- CACHD1 | c.3184G>T p.E1062* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV51559558, COSV99262366; called by muse, mutect2, varscan2
- CACNA1A | c.3963C>A p.F1321L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV64197130; called by mutect2, varscan2
- CACNA1A | c.2261C>A p.P754H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100802495; called by muse, mutect2, varscan2
- CACNA1A | c.2039C>A p.S680Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64214557; called by muse, mutect2, varscan2
- CACNA1B | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53112017, COSV99497666; called by muse, mutect2, varscan2
- CACNA1C | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59747910, COSV59785774; called by muse, mutect2, varscan2
- CACNA1E | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.41); catalogued as COSV62392856; called by muse, mutect2, varscan2
- CACNA1E | c.1886T>G p.F629C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100702799; called by muse, mutect2, varscan2
- CACNA1F | c.5144C>T p.S1715F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1557105428, COSV100544895; called by muse, mutect2, varscan2
- CACNA1F | c.3886C>A p.R1296S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM055910, CM158325, COSV100544896, COSV59902931; called by muse, mutect2, varscan2
- CACNA1F | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544898; called by muse, mutect2, varscan2
- CACNA1F | c.1566C>A p.C522* | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | catalogued as COSV100544900; called by muse, mutect2, varscan2
- CACNA1H | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100672682; called by muse, mutect2, varscan2
- CACNA1S | c.5261G>T p.R1754I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV100755028, COSV62938793; called by mutect2, varscan2
- CACNA1S | c.5012G>A p.G1671D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100755029; called by muse, mutect2, varscan2
- CACNA1S | c.3981G>T p.E1327D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as COSV100755030; called by muse, mutect2, varscan2
- CACNA2D3 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs777168401, COSV55535703, COSV55590414; called by muse, mutect2, varscan2
- CADPS | c.3748G>T p.E1250* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV51882892, COSV99338467; called by muse, mutect2, varscan2
- CADPS | c.2749T>G p.L917V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99338473; called by muse, mutect2, varscan2
- CALD1 | c.1893G>T p.K631N (on ENST00000361675 / NM_033138.4; = p.K376N on NM_004342.7) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100724266; called by muse, mutect2, varscan2
- CALHM6 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63991589, COSV63991722; called by muse, mutect2, varscan2
- CAMK1D | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV101123715; called by muse, mutect2, varscan2
- CAMK2N1 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100907002; called by muse, mutect2, varscan2
- CAPN1 | c.123T>G p.D41E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99658693; called by muse, mutect2, varscan2
- CAPS2 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV100157795; called by muse, mutect2, varscan2
- CAPSL | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV101274268; called by muse, mutect2
- CARD6 | c.1603A>C p.N535H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99620832; called by muse, mutect2, varscan2
- CARD9 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as rs778435234, COSV99395963; called by muse, mutect2, varscan2
- CARD9 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.918); catalogued as COSV100261199; called by muse, mutect2, varscan2
- CARMIL2 | c.2881C>A p.H961N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54666401, COSV99537726; called by muse, mutect2, varscan2
- CARMIL2 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs756446842, COSV54667968; called by muse, mutect2, varscan2
- CASP8 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51846504, COSV99965286, COSV99965729; called by muse, mutect2, varscan2
- CASQ2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs375598471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100824724; called by muse, mutect2, varscan2
- CASS4 | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV100824726; called by muse, mutect2, varscan2
- CBLL2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100081614; called by mutect2, varscan2
- CBWD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | catalogued as rs1554669939; called by mutect2, varscan2
- CBWD6 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 72/186 reads (39%) | catalogued as rs1368646032; called by muse, mutect2, varscan2
- CC2D2A | c.2661C>A p.F887L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1461261346, COSV67502184; called by muse, mutect2, varscan2
- CCDC117 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99968870; called by muse, mutect2, varscan2
- CCDC121 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1299824588, COSV99270207, COSV99270539; called by muse, mutect2, varscan2
- CCDC125 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs773623515, COSV101143608; called by muse, mutect2, varscan2
- CCDC138 | c.1916T>G p.F639C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99719142; called by muse, mutect2, varscan2
- CCDC150 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99776975; called by muse, mutect2, varscan2
- CCDC180 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100826730; called by muse, mutect2, varscan2
- CCDC186 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs532080412, COSV100990995, COSV65159686; called by muse, mutect2, varscan2
- CCDC39 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99869015, COSV99870886; called by muse, mutect2, varscan2
- CCDC39 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99869027; called by muse, mutect2, varscan2
- CCDC39 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99869036, COSV99870314; called by muse, mutect2, varscan2
- CCDC54 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV99660213; called by muse, mutect2, varscan2
- CCDC73 | c.1427C>A p.S476Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as COSV100067544, COSV58799301, COSV58801359; called by muse, mutect2, varscan2
- CCDC73 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs1370064416, COSV58794903, COSV58797375; called by muse, mutect2, varscan2
- CCDC80 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759648511, COSV52815608; called by muse, mutect2, varscan2
- CCDC82 | c.995C>A p.S332Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1430158819, COSV53592355; called by muse, mutect2
- CCDC82 | c.473A>C p.N158T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as COSV99567334; called by muse, mutect2, varscan2
- CCHCR1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs576883267, COSV99458887; called by muse, mutect2, varscan2
- CCKAR | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55162636; called by muse, mutect2, varscan2
- CCNB1IP1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62303098; called by muse, mutect2, varscan2
- CCNB3 | c.1376A>C p.K459T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV99329116; called by muse, mutect2, varscan2
- CCNB3 | c.1528T>G p.L510V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99329118; called by muse, mutect2, varscan2
- CCNE2 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV100353616, COSV100353769; called by muse, mutect2, varscan2
- CCP110 | c.2124C>A p.N708K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV101195282; called by muse, mutect2, varscan2
- CCPG1 | c.1688G>T p.R563I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99380409; called by muse, mutect2, varscan2
- CCRL2 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs201440539; called by muse, mutect2, varscan2
- CCT4 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV101075214, COSV66702150; called by muse, mutect2
- CCT6B | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100030545; called by muse, mutect2, varscan2
- CCZ1B | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV100367864; called by muse, mutect2, varscan2
- CD180 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99842259; called by muse, mutect2, varscan2
- CD207 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as rs370455494, COSV101338598; called by muse, mutect2, varscan2
- CD22 | c.1652G>T p.G551V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as COSV99323258; called by muse, mutect2, varscan2
- CD244 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV100458567; called by muse, mutect2, varscan2
- CD276 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.058); catalogued as rs943925889, COSV100573374; called by muse, mutect2, varscan2
- CD2AP | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV100830429; called by muse, mutect2, varscan2
- CD300LF | c.382+2T>C p.X128_splice | Splice Site (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100042780; called by muse, mutect2, varscan2
- CD34 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100178409; called by muse, mutect2, varscan2
- CD38 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99882731; called by muse, mutect2, varscan2
- CD58 | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101043894; called by muse, mutect2, varscan2
- CD7 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs779224116, COSV100444879; called by muse, mutect2, varscan2
- CD8B | c.644G>T p.G215V (on ENST00000331469 / NM_172213.4; = p.G185V on NM_172102.4) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100514532; called by muse, mutect2
- CDC16 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV52957818; called by muse, mutect2, varscan2
- CDC27 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99294912; called by muse, mutect2, varscan2
- CDC27 | c.568A>C p.N190H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs368750026, COSV50363891; called by muse, mutect2, varscan2
- CDC5L | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV65175963; called by muse, mutect2, varscan2
- CDC73 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66465307, COSV66466222; called by muse, mutect2, varscan2
- CDCA7 | c.775G>T p.E259* (on ENST00000347703 / NM_145810.3; = p.E338* on NM_031942.5) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100143530; called by mutect2, varscan2
- CDH10 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs545638636, COSV52579683, COSV52599865; called by muse, mutect2, varscan2
- CDH11 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs760693169, COSV51751688; called by muse, mutect2, varscan2
- CDH18 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99934842; called by muse, mutect2, varscan2
- CDH19 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV50979350, COSV50985804; called by muse, mutect2, varscan2
- CDH23 | c.9203C>T p.A3068V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as rs372434845; called by muse, mutect2, varscan2
- CDH26 | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99722488; called by mutect2, varscan2
- CDH7 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV59898067; called by muse, mutect2, varscan2
- CDHR3 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100488388, COSV99048421; called by muse, mutect2, varscan2
- CDHR3 | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100488390; called by muse, mutect2
- CDK13 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs781231247, COSV99475585; called by muse, mutect2, varscan2
- CDKL1 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs752698010, COSV99367514; called by mutect2, varscan2
- CDKL3 | c.1038A>G p.E346= | Splice Region (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99527880; called by muse, mutect2, varscan2
- CDKL5 | c.2349G>T p.M783I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101184335; called by muse, mutect2, varscan2
- CDKL5 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as rs747764150, COSV66111378; called by muse, mutect2, varscan2
- CDPF1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs764233150, COSV99415526; called by muse, mutect2, varscan2
- CDX1 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99199317; called by muse, mutect2, varscan2
- CEACAM7 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99137239; called by muse, mutect2, varscan2
- CEMIP | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV99586777; called by muse, mutect2, varscan2
- CENPE | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99478017; called by muse, mutect2, varscan2
- CENPF | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100871703; called by mutect2, varscan2
- CENPH | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as rs757244178, COSV99295434; called by muse, mutect2, varscan2
- CENPI | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV54501126, COSV99515434; called by muse, mutect2, varscan2
- CENPI | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV99515438; called by muse, mutect2, varscan2
- CENPJ | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1399575372, COSV67883291; called by muse, mutect2, varscan2
- CENPJ | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV101121514; called by muse, mutect2, varscan2
- CENPP | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99364106; called by muse, mutect2, varscan2
- CEP104 | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV100986623; called by muse, mutect2
- CEP120 | c.2934T>G p.I978M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100071138; called by muse, mutect2, varscan2
- CEP126 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99681074; called by muse, mutect2, varscan2
- CEP126 | c.1768C>A p.L590I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99681076; called by muse, mutect2, varscan2
- CEP128 | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as COSV99824814; called by muse, mutect2, varscan2
- CEP135 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1359395367, COSV57259422; called by muse, mutect2, varscan2
- CEP152 | c.3799C>T p.R1267C (on ENST00000380950 / NM_001194998.2; = p.R1211C on NM_014985.4) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs967551544, COSV100358832, COSV100359005; called by muse, mutect2, varscan2
- CEP162 | c.3951G>T p.K1317N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100003320, COSV57618196; called by muse, mutect2, varscan2
- CEP162 | c.2470A>C p.K824Q | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV100002844; called by muse, mutect2, varscan2
- CEP164 | c.2523G>T p.Q841H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99633415; called by muse, mutect2, varscan2
- CEP170B | c.1227C>A p.F409L (on ENST00000453495; = p.F338L on NM_015005.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV101371517; called by muse, mutect2, varscan2
- CEP19 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV99582480; called by muse, mutect2, varscan2
- CEP250 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698942; called by muse, mutect2, varscan2
- CEP350 | c.4751C>A p.S1584Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100854719; called by muse, mutect2, varscan2
- CEP63 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59675250; called by muse, mutect2, varscan2
- CEP78 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99450502; called by muse, mutect2, varscan2
- CEP97 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs965896242, COSV100511767, COSV100511972; called by muse, mutect2, varscan2
- CES5A | c.1687C>A p.L563I (on ENST00000290567 / NM_001143685.2; = p.L513I on NM_145024.3) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.03); catalogued as rs780292496, COSV99307581; called by muse, mutect2, varscan2
- CFAP43 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100829262; called by muse, mutect2, varscan2
- CFAP43 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99530765; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP54 | c.6578T>C p.I2193T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs761039476, COSV100733179; called by muse, mutect2, varscan2
- CFAP65 | c.4748C>T p.S1583F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV100445215, COSV58562681; called by muse, mutect2, varscan2
- CFAP91 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99847140; called by muse, mutect2, varscan2
- CFH | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100809613, COSV66408804; called by muse, varscan2
- CFH | c.3251T>G p.F1084C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV100809614; called by muse, varscan2
- CFHR5 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99888831; called by muse, mutect2, varscan2
- CFTR | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM962465, COSV50043138; called by muse, mutect2, varscan2
- CHAMP1 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100778810; called by muse, mutect2, varscan2
- CHCHD3 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99366252; called by muse, mutect2, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD5 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1008462843, COSV99313709; called by muse, mutect2, varscan2
- CHD5 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99313715; called by muse, mutect2, varscan2
- CHD5 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs774223603, COSV52419511, COSV52421012; called by muse, mutect2, varscan2
- CHD7 | c.5452C>G p.L1818V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV101418256; called by muse, mutect2, varscan2
- CHD9 | c.7153C>T p.R2385W (on ENST00000398510 / NM_001382353.1; = p.R2369W on NM_025134.7) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762440281, COSV99529193; called by muse, mutect2, varscan2
- CHEK2 | c.1372G>A p.V458I (on ENST00000382580 / NM_001005735.2; = p.V415I on NM_007194.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100101707; called by muse, mutect2, varscan2
- CHL1 | c.2581C>G p.H861D (on ENST00000397491 / NM_001253387.1; = p.H877D on NM_006614.4) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs1271106174, COSV56598317, COSV99851301; called by muse, mutect2, varscan2
- CHL1 | c.3052G>T p.G1018C (on ENST00000397491 / NM_001253387.1; = p.G1034C on NM_006614.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV56592136; called by muse, mutect2, varscan2
- CHM | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753331; called by muse, mutect2, varscan2
- CHN2 | c.914-1G>T p.X305_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99765157, COSV99765263; called by muse, mutect2
- CHRAC1 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99636197; called by muse, mutect2, varscan2
- CHRNA2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs200372256, COSV53557986; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA6 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748108347, COSV52378973; called by muse, mutect2, varscan2
- CHRNB3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV51493022; called by muse, varscan2
- CHST11 | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.129); catalogued as COSV57995558; called by muse, mutect2, varscan2
- CHST2 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.18); catalogued as COSV99046240; called by muse, mutect2, varscan2
- CHST7 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as rs764415985, COSV99332968; called by muse, mutect2, varscan2
- CHST8 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV52863259, COSV99381133; called by muse, mutect2
- CHSY3 | c.1951A>G p.N651D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV100519139; called by muse, mutect2, varscan2
- CIT | c.2178+1G>T p.X726_splice | Splice Site (SNP) | VAF 25/49 reads (51%) | catalogued as COSV99949744; called by muse, mutect2, varscan2
- CLASP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs1189932217, COSV55313347; called by muse, mutect2, varscan2
- CLCN4 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV101073840; called by muse, mutect2, varscan2
- CLCN6 | c.1938C>A p.F646L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.074); catalogued as COSV100411927; called by muse, mutect2, varscan2
- CLEC12A | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV58563009; called by muse, mutect2, varscan2
- CLEC4A | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99983649; called by muse, mutect2, varscan2
- CLEC4E | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV55226487; called by muse, mutect2, varscan2
- CLEC4G | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1199451543, COSV61002941; called by muse, mutect2, varscan2
- CLIC2 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV58935611, COSV58936165, COSV58936536; called by muse, mutect2, varscan2
- CLIC6 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1446830182, COSV100659231; called by muse, mutect2
- CLIC6 | c.1731C>A p.F577L (on ENST00000360731 / NM_001317009.2; = p.F559L on NM_053277.3) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1394513477, COSV100659161, COSV62447704; called by muse, mutect2, varscan2
- CLMN | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100112432; called by muse, mutect2, varscan2
- CLSTN1 | c.838G>A p.A280T (on ENST00000377298 / NM_001009566.3; = p.A270T on NM_014944.4) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs761776002, COSV63648369; called by muse, mutect2, varscan2
- CLUAP1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100489683, COSV58895077; called by muse, mutect2, varscan2
- CLVS1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs770693777, COSV57970881; called by muse, mutect2, varscan2
- CLVS2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs771884601, COSV99252842; called by muse, mutect2, varscan2
- CMPK1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs977859310, COSV100898571; called by muse, mutect2, varscan2
- CMTM5 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100198056; called by muse, mutect2, varscan2
- CMTR2 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100579179; called by muse, mutect2, varscan2
- CMYA5 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374313124, COSV71409406; called by muse, mutect2, varscan2
- CMYA5 | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV101484064; called by muse, mutect2, varscan2
- CMYA5 | c.11701C>A p.L3901I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV69745895; called by muse, mutect2, varscan2
- CNBD1 | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101582222, COSV73074098; called by muse, varscan2
- CNBD1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV101582223; called by muse, varscan2
- CNBD1 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV101582224; called by muse, mutect2, varscan2
- CNDP1 | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs922813317, COSV62595215; called by muse, mutect2, varscan2
- CNGA2 | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV61703463, COSV61705744, COSV61705946; called by muse, mutect2, varscan2
- CNKSR2 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668635; called by muse, mutect2, varscan2
- CNKSR2 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569272601, COSV54253998; called by muse, mutect2, varscan2
- CNOT1 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100409352; called by muse, mutect2, varscan2
- CNTF | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60157826; called by muse, mutect2, varscan2
- CNTLN | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV99264224; called by muse, mutect2, varscan2
- CNTN1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs773587445, COSV61638896; called by muse, mutect2
- CNTN1 | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as COSV100751437; called by muse, mutect2
- CNTN4 | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as rs759065205, COSV61873523; called by muse, mutect2, varscan2
- CNTN4 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753714750, COSV61867614; called by muse, varscan2
- CNTNAP1 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV99226471; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- CNTNAP4 | c.3055C>A p.L1019I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100271576; called by muse, mutect2, varscan2
- CNTNAP5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70470944; called by muse, mutect2
- COBLL1 | c.1813G>T p.E605* (on ENST00000392717; = p.E567* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99527974; called by muse, mutect2, varscan2
- COG3 | c.1931-1G>T p.X644_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100596533; called by muse, mutect2
- COL12A1 | c.7915G>T p.E2639* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100486025; called by muse, mutect2, varscan2
- COL12A1 | c.2502G>A p.W834* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100486027; called by muse, mutect2, varscan2
- COL16A1 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV54701020; called by muse, mutect2, varscan2
- COL19A1 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.36); catalogued as rs1229621328, COSV100506361; called by muse, mutect2, varscan2
- COL1A1 | c.2924T>G p.L975R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV99867282; called by muse, mutect2, varscan2
- COL1A2 | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs780395429, COSV51961449; called by muse, mutect2, varscan2
- COL22A1 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs1328551247, COSV100278666, COSV57332353; called by muse, mutect2, varscan2
- COL25A1 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.57); catalogued as COSV101211440; called by muse, mutect2, varscan2
- COL5A3 | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99318959; called by muse, mutect2, varscan2
- COL6A5 | c.5987C>A p.A1996D (on ENST00000312481; = p.A1992D on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV55204825, COSV99593286; called by muse, mutect2
- COL9A3 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100673417; called by muse, mutect2, varscan2
- COMMD9 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99661290; called by muse, mutect2, varscan2
- COPB2 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV100300664; called by muse, mutect2, varscan2
- COPG2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV58406958; called by muse, mutect2, varscan2
- COPS2 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54647663; called by muse, mutect2, varscan2
- COQ8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143816043; called by muse, mutect2, varscan2
- CORIN | c.2339A>C p.K780T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as COSV99903690; called by muse, mutect2, varscan2
- CP | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV99224142; called by muse, mutect2, varscan2
- CPEB3 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99799546; called by muse, mutect2, varscan2
- CPNE3 | c.759A>C p.K253N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV99547667; called by muse, mutect2, varscan2
- CPNE8 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV100504420, COSV58844019; called by muse, mutect2, varscan2
- CPSF6 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV57014900, COSV99879386; called by muse, mutect2, varscan2
- CR1 | c.4448C>A p.S1483Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100887626; called by muse, mutect2, varscan2
- CR1 | c.5584G>T p.G1862* | Nonsense Mutation (SNP) | VAF 54/130 reads (42%) | catalogued as COSV100887627, COSV65463694; called by muse, mutect2, varscan2
- CR1 | c.6115C>A p.P2039T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100887532, COSV100887629; called by muse, mutect2, varscan2
- CRB1 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV100957893; called by muse, mutect2, varscan2
- CRB1 | c.2632C>A p.L878I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV104426953, COSV66328840; called by muse, mutect2, varscan2
- CREBZF | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52629506, COSV99476299; called by muse, mutect2, varscan2
- CRISP3 | c.357G>T p.K119N (on ENST00000371159 / NM_001368123.1; = p.K101N on NM_006061.4) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV53823958, COSV53824577; called by muse, mutect2, varscan2
- CRPPA | c.877G>T p.E293* (on ENST00000407010 / NM_001368197.1; = p.E243* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV101235401; called by muse, mutect2, varscan2
- CRX | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as CD1410709, COSV99704494; called by muse, mutect2, varscan2
- CRYAB | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555165555, COSV99909855; called by muse, mutect2, varscan2
- CRYBA1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs527468370, COSV56600390; called by muse, mutect2, varscan2
- CRYBG3 | c.8409C>A p.F2803L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51716601; called by mutect2, varscan2
- CRYM | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99561783; called by muse, mutect2, varscan2
- CS | c.94-1G>T p.X32_splice | Splice Site (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100673239; called by muse, mutect2, varscan2
- CSGALNACT1 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV100175033; called by muse, mutect2, varscan2
- CSMD1 | c.9538T>G p.F3180V (on ENST00000520002; = p.F3179V on NM_033225.6) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100148333; called by muse, mutect2, varscan2
- CSMD1 | c.7484C>A p.S2495Y (on ENST00000520002; = p.S2494Y on NM_033225.6) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100148337; called by muse, mutect2
- CSMD1 | c.7118T>G p.F2373C (on ENST00000520002; = p.F2372C on NM_033225.6) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100148342; called by muse, mutect2, varscan2
- CSMD1 | c.3875C>A p.S1292Y (on ENST00000520002; = p.S1291Y on NM_033225.6) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100148346; called by muse, mutect2, varscan2
- CSMD3 | c.8090T>C p.I2697T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs764576448, COSV99835287; called by muse, mutect2, varscan2
- CSMD3 | c.5063G>T p.G1688V (on ENST00000297405 / NM_001363185.1; = p.G1584V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99835289; called by muse, varscan2
- CSMD3 | c.4997G>T p.R1666I (on ENST00000297405 / NM_001363185.1; = p.R1562I on NM_052900.3) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99835291; called by muse, varscan2
- CSMD3 | c.3136G>T p.E1046* (on ENST00000297405 / NM_001363185.1; = p.E942* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV99835295; called by muse, mutect2, varscan2
- CSN3 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100515327; called by muse, mutect2, varscan2
- CSPP1 | c.1389G>T p.E463D (on ENST00000676605; = p.E422D on NM_024790.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99138601; called by muse, mutect2, varscan2
- CSTF2T | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1211121710, COSV100484209; called by muse, mutect2, varscan2
- CSTF3 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as rs1023167813, COSV60612859, COSV60614211; called by muse, mutect2, varscan2
- CT55 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1194722384, COSV99358886; called by muse, mutect2, varscan2
- CTCF | c.934C>A p.H312N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50465013, COSV50501301, COSV99865446; called by muse, mutect2, varscan2
- CTDSP2 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV101143004; called by muse, mutect2, varscan2
- CTLA4 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV99044169, COSV99865288; called by muse, mutect2, varscan2
- CTNNA3 | c.320G>T p.R107I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100373610; called by muse, mutect2, varscan2
- CTSC | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773090897, COSV57058229; called by muse, mutect2, varscan2
- CTSO | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs769738268, COSV101467855, COSV70809895; called by muse, mutect2, varscan2
- CUL4B | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.271); catalogued as COSV100340593; called by muse, mutect2, varscan2
- CWC22 | c.2594G>T p.R865I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV99844307; called by muse, mutect2, varscan2
- CWC22 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748093590, COSV55427056; called by muse, mutect2
- CXCR3 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs764381576, COSV101031632; called by muse, mutect2, varscan2
- CYBB | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV66086175; called by muse, mutect2, varscan2
- CYBB | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101059760; called by muse, mutect2, varscan2
- CYFIP2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.692); catalogued as COSV59049626; called by muse, mutect2, varscan2
- CYLC2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs770475064, COSV66335876; called by muse, mutect2, varscan2
- CYP2W1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322251139, COSV58269364, COSV58271220; called by muse, mutect2, varscan2
- CYP4A11 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs146269651; called by muse, mutect2, varscan2
- CYP4F2 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99685813, COSV99686033; called by muse, mutect2, varscan2
- CYP7A1 | c.1510T>G p.L504V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100052400; called by muse, mutect2, varscan2
- CYP7B1 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306231531, COSV100041948, COSV59582775; called by muse, mutect2, varscan2
- CYSLTR1 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as COSV100964732; called by muse, mutect2
- CYSLTR1 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV100964733; called by muse, mutect2, varscan2
- CYSLTR1 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV100964734; called by muse, mutect2, varscan2
- DAO | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs888461072, COSV57321715; called by muse, mutect2, varscan2
- DAPP1 | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99596874; called by muse, mutect2, varscan2
- DBF4 | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV55995870, COSV55998047; called by muse, mutect2, varscan2
- DBNDD2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs773663734, COSV100619547; called by muse, varscan2
- DBT | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100923726; called by muse, mutect2
- DBX1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99910216; called by muse, mutect2, varscan2
- DCAF4L2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV60480325; called by muse, mutect2, varscan2
- DCBLD2 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.924); catalogued as COSV100472393; called by muse, mutect2, varscan2
- DCC | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500284, COSV59088771; called by muse, mutect2, varscan2
- DCC | c.1685G>T p.R562I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100500286, COSV59099654; called by muse, mutect2, varscan2
- DCDC1 | c.3374A>G p.D1125G (on ENST00000597505 / NM_001367979.1; = p.D232G on NM_020869.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100338304; called by muse, mutect2, varscan2
- DCHS1 | c.6380G>A p.R2127H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs142577975; called by muse, mutect2, varscan2
- DCN | c.986T>A p.L329H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99272277; called by muse, mutect2
- DCUN1D1 | c.106A>C p.K36Q | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV99489902; called by muse, mutect2, varscan2
- DDIAS | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs143540019, COSV61273442; called by mutect2, varscan2
- DDN | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100305187; called by muse, mutect2, varscan2
- DDO | c.763C>A p.L255I (on ENST00000368924 / NM_001368172.1; = p.L196I on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs1189354583, COSV100927850, COSV64470680; called by muse, mutect2, varscan2
- DDR2 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV100906603; called by muse, mutect2, varscan2
- DDX25 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as COSV54988585; called by muse, mutect2, varscan2
- DDX5 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs782356381, COSV99857990; called by muse, mutect2, varscan2
- DDX50 | c.460+1G>T p.X154_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV101007247; called by muse, mutect2, varscan2
- DDX50 | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101007249; called by muse, mutect2, varscan2
- DDX56 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144918436, COSV99345963; called by muse, mutect2, varscan2
- DDX60 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs758196490, COSV67094909; called by muse, mutect2, varscan2
- DEFB127 | c.70T>C p.C24R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101213837; called by muse, mutect2, varscan2
- DENND1C | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs373575393; called by muse, mutect2, varscan2
- DENND2A | c.1790C>A p.S597Y | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99326169; called by muse, mutect2, varscan2
- DENND2B | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs567812901, COSV100567490, COSV100568034; called by muse, mutect2, varscan2
- DENND2B | c.2758C>T p.L920F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100567491; called by muse, mutect2, varscan2
- DENND2C | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101283933; called by muse, mutect2, varscan2
- DENND5B | c.3127C>A p.L1043I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100171510; called by muse, mutect2, varscan2
- DEPDC1 | c.1931C>A p.S644* (on ENST00000456315 / NM_001114120.3; = p.S360* on NM_017779.6) | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100920324; called by muse, mutect2, varscan2
- DEPDC1 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs777967692, COSV100920237; called by muse, mutect2, varscan2
- DEPDC1B | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1311415862, COSV99409628; called by muse, mutect2, varscan2
- DEPDC7 | c.1135G>T p.E379* (on ENST00000241051 / NM_001077242.2; = p.E370* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as rs757386072, COSV99572751; called by muse, mutect2, varscan2
- DGAT2L6 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100283999; called by muse, mutect2, varscan2
- DGCR6L | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99956857; called by muse, mutect2, varscan2
- DGKB | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs562219154, COSV51790648, COSV51815168; called by muse, mutect2, varscan2
- DGKG | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99403407; called by muse, mutect2, varscan2
- DGKG | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs774928407, COSV99403410; called by muse, mutect2, varscan2
- DGKK | c.3160C>A p.Q1054K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101053013, COSV65708871; called by muse, mutect2, varscan2
- DGKK | c.2242T>A p.F748I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as COSV101053014; called by muse, mutect2, varscan2
- DHX32 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99501681; called by muse, mutect2
- DHX35 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as rs1438837325, COSV52668656; called by muse, mutect2, varscan2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2, varscan2
- DIAPH3 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV99933611; called by muse, mutect2, varscan2
- DICER1 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100602134; called by mutect2, varscan2
- DIO1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs766339963, COSV59517500; called by muse, mutect2, varscan2
- DIP2B | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99998576; called by muse, mutect2, varscan2
- DIPK2A | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100237188; called by muse, mutect2, varscan2
- DISP1 | c.3538C>T p.P1180S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52659563; called by muse, mutect2, varscan2
- DKC1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV101059884; called by muse, mutect2, varscan2
- DLAT | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs940082519, COSV99734717; called by muse, mutect2, varscan2
- DLC1 | c.2101G>T p.E701* (on ENST00000276297 / NM_001348081.2; = p.E264* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99363280; called by muse, mutect2, varscan2
- DLEC1 | c.4963C>T p.R1655W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs374917641; called by muse, mutect2, varscan2
- DLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as rs374177340, COSV101074026; called by muse, mutect2, varscan2
- DMAP1 | c.197+1G>A p.X66_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100261714; called by muse, mutect2, varscan2
- DMBT1 | c.4888G>T p.A1630S (on ENST00000338354 / NM_001377530.1; = p.A873S on NM_004406.3) | Missense Mutation (SNP) | VAF 177/370 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.316); catalogued as COSV100353066; called by muse, mutect2, varscan2
- DMD | c.10795C>A p.Q3599K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs772199578, COSV58898758; called by muse, mutect2, varscan2
- DMD | c.6856G>T p.E2286* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as CM098440, COSV100627370; called by muse, mutect2, varscan2
- DMGDH | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99669029; called by muse, mutect2, varscan2
- DMRT2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770503994, COSV99426094; called by muse, mutect2, varscan2
- DMRT2 | c.999A>C p.R333S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99426096; called by muse, mutect2, varscan2
- DMXL1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs138186062; called by muse, mutect2, varscan2
- DMXL1 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100224017; called by muse, mutect2, varscan2
- DMXL1 | c.3023A>T p.E1008V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV100224020; called by muse, mutect2, varscan2
- DMXL2 | c.4950A>C p.E1650D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99196406; called by muse, mutect2, varscan2
- DNAH10 | c.10530A>C p.K3510N (on ENST00000409039; = p.K3449N on NM_207437.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101292288; called by muse, mutect2, varscan2
- DNAH10 | c.12649G>T p.E4217* (on ENST00000409039; = p.E4156* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV101292289; called by muse, mutect2, varscan2
- DNAH10 | c.12799G>T p.E4267* (on ENST00000409039; = p.E4206* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as COSV53020358; called by muse, mutect2, varscan2
- DNAH11 | c.12897A>G p.I4299M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.266); catalogued as COSV100179346; called by muse, mutect2, varscan2
- DNAH17 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101103103, COSV67751702; called by muse, mutect2, varscan2
- DNAH2 | c.2750G>A p.R917H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs372631936; called by muse, mutect2, varscan2
- DNAH2 | c.2988A>C p.E996D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV101209343; called by muse, mutect2, varscan2
- DNAH2 | c.5270G>A p.R1757H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs776701910, COSV66718578; called by muse, mutect2, varscan2
- DNAH2 | c.5724C>G p.G1908= | Splice Region (SNP) | VAF 14/65 reads (22%) | catalogued as COSV101209344; called by muse, mutect2, varscan2
- DNAH2 | c.12038A>G p.D4013G | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209345; called by muse, mutect2, varscan2
- DNAH3 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV99767702; called by muse, mutect2, varscan2
- DNAH7 | c.6205C>A p.H2069N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767399727, COSV100415335; called by muse, mutect2, varscan2
- DNAH7 | c.4151G>T p.R1384I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415336; called by muse, mutect2, varscan2
- DNAH8 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs772099828, COSV100545525; called by muse, mutect2, varscan2
- DNAH8 | c.7826T>C p.I2609T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100545526, COSV59423736; called by muse, mutect2, varscan2
- DNAH8 | c.13050C>A p.F4350L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1404091935, COSV59443699; called by muse, mutect2, varscan2
- DNAH9 | c.2408G>T p.R803I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs753142472, COSV52336899, COSV52340773; called by muse, mutect2, varscan2
- DNAH9 | c.6026T>C p.V2009A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99305983; called by muse, mutect2, varscan2
- DNAH9 | c.11071G>A p.D3691N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs138333222; called by muse, mutect2, varscan2
- DNAH9 | c.11430C>A p.F3810L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs956358261, COSV52343252, COSV52347043; called by muse, mutect2, varscan2
- DNAI3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99641887; called by muse, mutect2, varscan2
- DNAI4 | c.1832C>A p.S611Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100925278; called by muse, mutect2
- DNAJB4 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100883461; called by muse, mutect2, varscan2
- DNAJC12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs369180417; called by muse, mutect2, varscan2
- DNAJC25 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100543375, COSV57957987; called by muse, mutect2, varscan2
- DNAJC6 | c.2454G>T p.E818D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.33); catalogued as COSV99674915; called by muse, mutect2, varscan2
- DNAJC9 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99654719; called by muse, mutect2, varscan2
- DNAJC9 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99654721; called by muse, mutect2, varscan2
- DNASE1L1 | c.774+2T>C p.X258_splice | Splice Site (SNP) | VAF 36/111 reads (32%) | catalogued as COSV99185977; called by muse, mutect2, varscan2
- DNMT3B | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99141841; called by muse, varscan2
- DNPEP | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99815206; called by muse, mutect2, varscan2
- DOCK1 | c.3032T>A p.F1011Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99729943; called by muse, mutect2, varscan2
- DOCK10 | c.4333C>T p.R1445* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as rs764765523, COSV51418209; called by muse, mutect2, varscan2
- DOCK11 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1216228275, COSV99353894; called by muse, mutect2, varscan2
- DOCK11 | c.4127C>T p.S1376L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.655); catalogued as COSV99353895; called by muse, mutect2, varscan2
- DOCK3 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774398189, COSV56509467; called by mutect2, varscan2
- DOCK4 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV70314308; called by muse, mutect2, varscan2
- DOCK4 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365271106, COSV70315040; called by muse, mutect2, varscan2
- DOCK5 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99376948; called by muse, mutect2, varscan2
- DOCK5 | c.5201G>T p.R1734I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV99376951; called by muse, mutect2
- DOCK7 | c.5228C>A p.S1743Y (on ENST00000635253 / NM_001367561.1; = p.S1712Y on NM_033407.3) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99224577; called by muse, mutect2, varscan2
- DOCK7 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99224585; called by muse, mutect2, varscan2
- DOP1A | c.3938C>A p.S1313Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs149855399, COSV99381982, COSV99381995; called by mutect2, varscan2
- DPP4 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100858888; called by muse, mutect2, varscan2
- DPP8 | c.826G>T p.E276* (on ENST00000341861 / NM_001320875.2; = p.E260* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV55676443; called by muse, mutect2, varscan2
- DPYS | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559507379, COSV60908338; called by muse, mutect2, varscan2
- DPYSL3 | c.543C>A p.L181= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100575140; called by muse, mutect2, varscan2
- DRP2 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100871923; called by muse, mutect2, varscan2
- DSCC1 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100558334; called by muse, mutect2, varscan2
- DSEL | c.2615G>A p.G872D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV100025687; called by muse, mutect2, varscan2
- DSEL | c.758A>C p.K253T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.665); catalogued as COSV100025690; called by muse, mutect2, varscan2
- DSG2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs753052874, COSV55199650; called by muse, mutect2
- DSG3 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57124588; called by muse, mutect2, varscan2
- DSG3 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99934202; called by muse, mutect2, varscan2
- DSG4 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100355942; called by muse, mutect2, varscan2
- DSG4 | c.1020A>C p.E340D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100355943; called by muse, mutect2, varscan2
- DSP | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.94); catalogued as COSV101131289; called by muse, mutect2, varscan2
- DSP | c.5148G>T p.E1716D | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.918); catalogued as COSV101131290; called by muse, mutect2, varscan2
- DSPP | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV99217419; called by muse, mutect2, varscan2
- DST | c.14978C>A p.S4993Y (on ENST00000361203 / NM_001374722.1; = p.S2581Y on NM_015548.5) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs531201352, COSV104390747, COSV55018209; called by muse, mutect2, varscan2
2,863 further variants in this file (2,153 protein-altering or splice-affecting, 616 silent, 94 other) are not listed here.
